Surgical pathology report (de-identified scan), TCGA case TCGA-85-7710, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Asterand, specimen TCGA-85-7710-01A (Primary Tumor).

[page 1 of 3]
TCGA Pathology Reports

Asterand Case ID	Open Clinica Subject ID	TCGA	Gross Description
		85-7710	Labeled left lingular. Received fresh for intraoperative consultation is a stapled 5.7 x 3.6 cm wedge biopsy of lung tissue containing a 2.4 x 1.5 cm stellate firm tan-white subpleural mass which causes puckering of the overlying pleura. The mass comes to within 1.2 cm of the stapled margin. The background lung tissue is soft, tan-pink and without other lesions

[page 2 of 3]
Microscopic Description	Diagnosis Details	Formatted Path Report
Permanent sections confirm the frozen section diagnosis. The tumor is invasive squamous cell carcinoma that is moderately differentiated. There is prominent intracellular bridging and focal keratinization.	LUNG CARCINOMA CHECKLIST  1. Tumor Type: Squamous cell carcinoma. 2. Tumor grade: Moderately differentiated. 3. Tumor location: Left lingula. 4. Tumor size: 2.4 cm. 5. Angiolymphatic invasion: No. 6. Bronchial margin: N/A. 7. Pleural involvement: Subpleural. 8. Lymph nodes: 0 positive out of 1 found. 9. Size of largest metastatic deposit: N/A cm. 10. TNM: T1b N0 MX. 	LUNG TISSUE CHECKLIST Specimen type: Wedge resection, lobectomy Tumor site: Lung Tumor size: 2.4 x 1.5 cm Histologic type: Squamous cell carcinoma Histologic grade: Moderately differentiated Tumor extent: Not specified Other tumor nodules: Not specified Lymph nodes: 0/1 positive for metastasis (Ap window lymph node 0/1) Lymphatic invasion: Absent Venous invasion: Absent Margins: Not specified Evidence of neo-adjuvant treatment: Not specified Additional pathologic findings: Not specified Comments: None

[page 3 of 3]
Date of Procurement

Source: NCI Genomic Data Commons file 0936e843-52ef-4ec3-9357-51b4116ac598 (TCGA-85-7710.B20F51FD-6A9B-4A13-AE9C-AF25D60C9BBD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).